Somatic mutation profile of tumor specimen MMRF_1484_1_BM_CD138pos (aliquot MMRF_1484_1_BM_CD138pos_T1_KBS5U_L02994) from MMRF case MMRF_1484, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.4 years (26,439 days).
Specimen MMRF_1484_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f71313d0-0d0d-49c7-90e1-97421c684e14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1484_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1484_1_PB_Whole_C3_KBS5U_L03002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8691e2e3-78c0-4a8c-8d3c-b561c568c40c

The open-access MAF lists 89 somatic variants for this specimen: 45 protein-altering or splice-affecting, 6 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 20, Intron 11, Silent 6, RNA 2, Nonsense Mutation 2, 3'Flank 2, Splice Site 2, 5'UTR 2, Frame Shift Del 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 112/241 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.988); catalogued as rs375159565; called by muse, mutect2, varscan2
- ATP7B | c.3670C>T p.R1224W | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs746893370; called by muse, mutect2, varscan2
- BEST2 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV50358999; called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.23A>C p.Q8P | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as COSV64958912; called by muse, mutect2, varscan2
- DDX56 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs542305571; called by muse, mutect2, varscan2
- GPR139 | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1383243009; called by muse, mutect2
- HUNK | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.12); catalogued as rs532775196, COSV54235037; called by muse, mutect2, varscan2
- IGHV2-70 | c.313A>C p.N105H | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs377238058; called by muse, varscan2
- IGHV2-70 | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376102764; called by muse, varscan2
- IGHV2-70 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs72690597; called by muse, varscan2
- ITGA2B | c.880A>T p.T294S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.436); catalogued as COSV52232183; called by muse, mutect2, varscan2
- OR2B6 | c.649T>A p.S217T | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as rs1317600991; called by muse, mutect2, varscan2
- PCLO | c.12275C>T p.T4092I | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV61632431; called by muse, mutect2, varscan2
- SLC17A1 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.119); catalogued as rs1453748397; called by muse, mutect2, varscan2
- SLC5A8 | c.8C>G p.T3R | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs1400867028; called by muse, mutect2, varscan2
- SMAD2 | c.364G>T p.G122* | Nonsense Mutation (SNP) | VAF 5/95 reads (5%) | catalogued as COSV100054058, COSV51051607; called by muse, mutect2
- ZNF525 | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1051942833; called by muse, mutect2, varscan2
- ABCC9 | c.1502G>A p.G501D | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD2 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- COL3A1 | c.3861G>C p.L1287F | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ERCC6 | c.4021G>A p.V1341M | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- FAM78B | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FYB2 | c.612A>T p.K204N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HIP1R | c.2915C>T p.S972F | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HJURP | c.118-20_137del p.X40_splice | Splice Site (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel
- HOXB9 | c.559A>G p.K187E | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HUWE1 | c.9599T>G p.L3200R | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IGHV2-70D | c.52T>G p.L18V | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, varscan2
- IGLV4-3 | c.330C>G p.H110Q | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- LRRIQ1 | c.3622A>T p.S1208C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- LYN | c.71T>A p.V24E | Missense Mutation (SNP) | VAF 141/317 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, varscan2
- OR10G8 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 112/251 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PHF13 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C3 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLPPR5 | c.735T>A p.Y245* | Nonsense Mutation (SNP) | VAF 74/140 reads (53%) | called by muse, mutect2, varscan2
- PRAMEF2 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- PRCC | c.1003A>G p.M335V | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFX5 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 97/218 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC13A4 | c.682C>A p.H228N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SYNE2 | c.6714+2T>G p.X2238_splice | Splice Site (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- TAC1 | c.306del p.F103Lfs*4 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | called by mutect2, pindel, varscan2
- TERF2IP | c.92_94del p.F31del | In Frame Del (DEL) | VAF 44/115 reads (38%) | called by mutect2, pindel, varscan2
- TRIO | c.6707T>G p.F2236C | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- WNK2 | c.2086C>G p.Q696E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ZNF236 | c.2551T>A p.F851I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- DNAH6 | c.135A>G p.E45= | Silent (SNP) | VAF 85/168 reads (51%) | called by muse, mutect2, varscan2
- H3C7 | c.66C>A p.A22= | Silent (SNP) | VAF 68/165 reads (41%) | called by muse, mutect2, varscan2
- KIAA1109 | c.11964A>G p.K3988= | Silent (SNP) | VAF 73/168 reads (43%) | called by muse, mutect2, varscan2
- LRRC19 | c.420A>T p.V140= | Silent (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- NRXN3 | c.543C>T p.N181= (on ENST00000557594 / NM_001272020.2; = p.N813= on NM_004796.6) | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs755216631, COSV55318638, COSV55336599; called by muse, mutect2, varscan2
- UNC80 | c.3162G>A p.T1054= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs367811380, COSV55893266; called by muse, mutect2, varscan2
- AMIGO1 | chr1:109504761 A>C | 3'Flank (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- AMIGO2 | c.*784T>C | 3'UTR (SNP) | VAF 106/228 reads (46%) | called by muse, mutect2, varscan2
- ANXA1 | c.-14-628C>A | Intron (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- ATP10A | c.3166-152C>T | Intron (SNP) | VAF 8/16 reads (50%) | catalogued as rs546838081; called by muse, mutect2, varscan2
- BMPER | c.*1939G>T | 3'UTR (SNP) | VAF 12/40 reads (30%) | catalogued as COSV51833884; called by muse, mutect2, varscan2
- BTBD3 | chr20:11890728 G>A | 5'Flank (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- C11orf87 | c.*4457C>T | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- CADM1 | c.*1648T>C | 3'UTR (SNP) | VAF 21/33 reads (64%) | called by muse, mutect2, varscan2
- CPEB4 | c.-573C>A | 5'UTR (SNP) | VAF 27/77 reads (35%) | catalogued as rs926172514; called by muse, mutect2, varscan2
- DEFB118 | c.*657C>G | 3'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- DEGS2 | c.*177C>T | 3'UTR (SNP) | VAF 32/71 reads (45%) | catalogued as rs1008600907; called by muse, mutect2, varscan2
- FAM131B | c.*2188G>A | 3'UTR (SNP) | VAF 28/60 reads (47%) | catalogued as rs113104457; called by muse, mutect2, varscan2
- G2E3 | c.*1860T>A | 3'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+21069G>C | Intron (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- GNL3L | c.-47-66A>C | Intron (SNP) | VAF 49/59 reads (83%) | called by muse, mutect2, varscan2
- GRIP1 | c.*848A>C | 3'UTR (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- HMCES | c.*520_*523del | 3'UTR (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- IARS1 | c.-8+909A>G | Intron (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2
- IARS1 | c.-8+907A>T | Intron (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2
- KNG1 | c.*1004C>T | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- LTB | c.162+86del | Intron (DEL) | VAF 24/72 reads (33%) | called by pindel, varscan2
- LTB | c.162+80T>G | Intron (SNP) | VAF 26/61 reads (43%) | called by muse, varscan2
- MAFK | c.*1394T>G | 3'UTR (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
- NALCN | c.*301T>G | 3'UTR (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- P2RX1 | c.137+147G>T | Intron (SNP) | VAF 58/126 reads (46%) | called by muse, mutect2, varscan2
- PGD | c.*11C>G | 3'UTR (SNP) | VAF 90/187 reads (48%) | called by muse, mutect2, varscan2
- PRPF38B | c.*528A>G | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, varscan2
- PRPF38B | c.*643A>G | 3'UTR (SNP) | VAF 20/52 reads (38%) | called by muse, varscan2
- RGMB | c.*887C>T | 3'UTR (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- SCAMP2 | c.*394G>T | 3'UTR (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.*984T>C | 3'UTR (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- SPCS2P4 | n.639C>T | RNA (SNP) | VAF 34/138 reads (25%) | called by muse, mutect2, varscan2
- SSPOP | n.10801T>G | RNA (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- TRIM73 | chr7:75414888 T>G | 3'Flank (SNP) | VAF 23/55 reads (42%) | catalogued as rs397392; called by muse, mutect2, varscan2
- TSPAN19 | c.-3A>C | 5'UTR (SNP) | VAF 60/129 reads (47%) | called by muse, mutect2, varscan2
- UBAC2 | c.31+62G>T | Intron (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- ULK2 | c.*40+1279C>G | Intron (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- ZNF439 | c.*167G>T | 3'UTR (SNP) | VAF 87/180 reads (48%) | called by muse, mutect2, varscan2
